Gene-level copy-number profile of tumor specimen TCGA-30-1714-01A from TCGA case TCGA-30-1714, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.5 years (25,032 days).
Specimen TCGA-30-1714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3a5d57c7-62f9-48cc-9b9e-b8d437d7c86d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1714-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d84fee13-39a9-4f1d-9bcb-0622f443b5ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,600; copy number 2: 16,490; copy number 3: 18,970; copy number 4: 16,093; copy number 5: 4,955; copy number 6: 161; copy number 7: 22; copy number 8: 402; copy number 10: 6; copy number 11: 48; copy number 17: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1714-01A-02D-0559-01): tumor purity 0.9, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 548 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:18,522,735–18,674,001, 2 genes, copy number 7 (within-gene range 5–7): MIR548A1HG, MIR548A1.
- chr6:123,589,711–124,825,640, 3 genes, copy number 10 (within-gene range 2–10): AL133257.1, NKAIN2, AL354936.1.
- chr6:128,580,113–128,639,653, 3 genes, copy number 10: EEF1DP5, Y_RNA, AL080315.1.
- chr6:141,403,240–142,637,889, 12 genes, copy number 8 (within-gene range 6–8): AL355596.2, AL355596.1, RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1.
- chr6:150,599,883–150,843,665, 1 gene, copy number 7 (within-gene range 5–7): PLEKHG1.
- chr6:150,827,663–151,470,101, 19 genes, copy number 7: PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1.
- chr19:27,638,483–40,898,282, 508 genes, copy number 8–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,600. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
